Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2J9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2J9-06A (Metastatic).

DIAGNOSIS

Patient ID – Sample ID

(A) LEFT CHEST AND LEFT AXILLARY DISSECTION:

MALIGNANT MELANOMA METASTATIC TO FIVE OF THIRTY-SEVEN LYMPH NODES (5/37).

Largest tumor size 80 x 50 mm (gross).

Extracapsular capsular extension present.

(B) ADDITIONAL SUPERIOR MARGIN:

Fibroadipose tissue. Melanoma not identified.

Entire report and diagnosis completed by

108-0-3

Melanoma, NOS 8720/3

Site: lymph node, axillary C17.3

hw 7/24/11

GROSS DESCRIPTION

(A) WIDE EXCISION RECURRENT MELANOMA LEFT CHEST IN CONTINUITY WITH LEFT AXILLARY DISSECTION, SHORT STITCH SUPERIOR, LONG STITCH MEDIAL - A skin ellipse with subcutaneous tissue (29.0 x 2.0 cm, 5.0 cm deep) with an attached left axillary dissection specimen (25.0 x 11.0 x 2.0 cm). The skin ellipse contains a scar measuring 21.0 cm in length. The skin ellipse margins are inked as per ink code. There is a centrally located (12.0 cm from medial margin) round fleshy 0.2 cm nodule in the subcutaneous soft tissue grossly abutting the superior margin. The axillary dissection specimen reveals multiple lymph nodes. The two largest masses (8.0 x 5.0 x 1.5 and 2.5 x 1.5 x 1.0 cm) are grossly involved with tumor, containing pigment. The remaining possible lymph nodes range in size from 0.6 to 2.0 cm. Representative sections of skin with tumor and all lymph nodes are submitted as per section code. Representative sections of the tumor mass are submitted for Tumor Banking.

INK CODE: Blue = superior; orange = inferior.

SECTION CODE: A1, section of skin ellipse with tumor nodule; A2, representative skin with scar; A3, A4, representative section of largest mass; A5, second largest lymph node mass, bisected; A6, A7, third largest lymph node, bisected; A8, one possible lymph node, bisected; A9, one possible lymph node, bisected; A10, two possible lymph nodes; A11, three possible lymph nodes; A12, three possible lymph nodes; A13, three possible lymph nodes; A14, three possible lymph nodes; A15, three possible lymph nodes; A16, three possible lymph nodes; A17, three possible lymph nodes; A18, three possible lymph nodes; A19, three possible lymph nodes; A20, three possible lymph nodes.

(B) ADDITIONAL SUPERIOR MARGIN, STITCH TRUE MARGIN - A 7.2 x 3.0 x 1.0 cm portion of unremarkable subcutaneous soft tissue. Specimen is inked blue representing the true superior margin. Specimen is entirely submitted in cassette B1-B7.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 8040a60a-9787-4930-88ad-19504418171b (TCGA-D3-A2J9.B83A4AE9-7ADB-482C-9AA5-53E553F54446.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).